Somatic mutation profile of tumor specimen 0DI3M1 from CCDI case PBBVHG, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.8 years (5,787 days).
Specimen 0DI3M1: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 54452200-0946-4ac7-8025-a2847672ba9f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3JH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e788d5e-063c-4a2b-a63e-f3ffdfd387b0

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 4, Splice Site 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACBD7 | c.259G>A p.G87R | Missense Mutation (SNP) | VAF 235/1237 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs200704311, COSV62252241; called by muse, mutect2, varscan2
- FAT2 | c.9370G>A p.D3124N | Missense Mutation (SNP) | VAF 36/1372 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1474895969; called by muse, mutect2
- NRIP2 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 80/527 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs752617615, COSV61701457; called by muse, mutect2, varscan2
- RHBDL3 | c.1202C>T p.P401L | Missense Mutation (SNP) | VAF 361/674 reads (54%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.061); catalogued as rs1294396681; called by muse, mutect2, varscan2
- UNC45B | c.2246G>A p.R749Q | Missense Mutation (SNP) | VAF 181/751 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs772024538, COSV52092901; called by muse, mutect2, varscan2
- URGCP | c.1172G>A p.R391H (on ENST00000453200 / NM_001077663.3; = p.R382H on NM_017920.4) | Missense Mutation (SNP) | VAF 132/764 reads (17%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.847); catalogued as rs1449282721, COSV56248527; called by muse, mutect2, varscan2
- DNAH8 | c.2341A>G p.I781V | Missense Mutation (SNP) | VAF 237/995 reads (24%) | SIFT tolerated (0.87); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FAT2 | c.8842+1G>T p.X2948_splice | Splice Site (SNP) | VAF 161/639 reads (25%) | called by muse, mutect2, varscan2
- IRS2 | c.1679C>T p.S560L | Missense Mutation (SNP) | VAF 219/528 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SCNN1D | c.254C>G p.T85R (on ENST00000338555; = p.T249R on NM_001130413.4) | Missense Mutation (SNP) | VAF 166/352 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- DNAH2 | c.1635C>T p.S545= | Silent (SNP) | VAF 206/794 reads (26%) | catalogued as rs776923082, COSV50020180; called by muse, varscan2
- HABP2 | c.1617C>T p.V539= | Silent (SNP) | VAF 73/1282 reads (6%) | called by muse, mutect2
- MAPK13 | c.528C>T p.D176= | Silent (SNP) | VAF 243/469 reads (52%) | catalogued as rs762479045, COSV99275008; called by muse, mutect2, varscan2
- PABPC1L | c.393G>A p.A131= | Silent (SNP) | VAF 216/432 reads (50%) | catalogued as rs757340806; called by muse, mutect2, varscan2
- LRRC4B | c.*28G>A | 3'UTR (SNP) | VAF 32/146 reads (22%) | catalogued as rs758341207, COSV65350530; called by muse, mutect2, varscan2
- WDR91 | c.-19T>C | 5'UTR (SNP) | VAF 51/227 reads (22%) | called by muse, mutect2, varscan2
